Somatic mutation profile of tumor specimen TCGA-AX-A06B-01A (aliquot TCGA-AX-A06B-01A-11W-A027-09) from TCGA case TCGA-AX-A06B, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 72.1 years (26,348 days).
Specimen TCGA-AX-A06B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e3fa100-5716-4fd8-8ae1-d151f6c9e436.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A06B-10A (Blood Derived Normal), aliquot TCGA-AX-A06B-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f071de8-f200-4d1f-85f4-8a6656f48042

The open-access MAF lists 48 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 31, Silent 10, Splice Site 2, Splice Region 1, Nonsense Mutation 1, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 209/323 reads (65%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1131691025, COSV52677105, COSV52952688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GALNT2 | c.880C>A p.Q294K | Missense Mutation (SNP) | VAF 110/242 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV64003573; called by muse, mutect2
- B3GALNT2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 105/238 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs545999890, COSV64003575; called by muse, mutect2
- C9 | c.939_941del p.V314del | In Frame Del (DEL) | VAF 76/210 reads (36%) | catalogued as rs747558580; called by pindel, varscan2
- CERS2 | c.905A>C p.Y302S | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV54978713; called by muse, mutect2, varscan2
- CLIC2 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs782037891, COSV58935875, COSV58936587; called by muse, mutect2, varscan2
- CLP1 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV57054067; called by muse, mutect2, varscan2
- CSMD3 | c.10952T>C p.L3651P (on ENST00000297405 / NM_001363185.1; = p.L3482P on NM_052900.3) | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52129395; called by muse, mutect2, varscan2
- DHX29 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 191/412 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs562197100, COSV52417144; called by muse, varscan2
- EMILIN3 | c.1151G>A p.C384Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60035478; called by muse, mutect2, varscan2
- EPCAM | c.184+1G>C p.X62_splice | Splice Site (SNP) | VAF 12/110 reads (11%) | catalogued as rs866758817, COSV55392638, COSV99764316; called by muse, mutect2
- FCRLB | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.872); catalogued as COSV61059470; called by muse, mutect2, varscan2
- FILIP1 | c.996A>T p.R332S | Missense Mutation (SNP) | VAF 142/664 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV52725017; called by muse, mutect2, varscan2
- FRAS1 | c.1097A>G p.K366R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV53597043; called by muse, mutect2, varscan2
- FRMD4B | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as rs1037036938, COSV68329022; called by muse, mutect2, varscan2
- FXR1 | c.1421G>A p.S474N | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV59761656; called by muse, mutect2, varscan2
- HYPK | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0.373); catalogued as COSV51038565; called by muse, mutect2
- LNPK | c.387C>A p.Y129* | Nonsense Mutation (SNP) | VAF 66/245 reads (27%) | catalogued as COSV55822893; called by muse, mutect2, varscan2
- MYO16 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV51782497; called by muse, mutect2
- NUFIP2 | c.1238A>G p.N413S | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56602552; called by muse, mutect2, varscan2
- OPCML | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770223558, COSV59410726; called by muse, mutect2, varscan2
- PLEKHG1 | c.3983G>A p.R1328H | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs754481715, COSV62045900; called by muse, mutect2, varscan2
- PRL | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1238214033, COSV60591501; called by muse, mutect2, varscan2
- SIPA1L2 | c.3351G>A p.T1117= | Splice Region (SNP) | VAF 14/69 reads (20%) | catalogued as rs140868197; called by muse, mutect2, varscan2
- SLC22A3 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs189883656; called by muse, mutect2, varscan2
- SMC1A | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59128116; called by muse, mutect2, varscan2
- SPHKAP | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200812632, COSV60871952; called by muse, mutect2, varscan2
- TTC27 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs17012268; called by muse, mutect2, varscan2
- UBE4A | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 173/556 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as rs781711602, COSV52803128; called by muse, mutect2, varscan2
- UCHL5 | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1268610155, COSV66485892; called by muse, mutect2, varscan2
- WDR33 | c.1544T>G p.I515S | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV59247140; called by muse, mutect2, varscan2
- ZNF343 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.408); catalogued as rs1282520196, COSV53853142; called by muse, mutect2, varscan2
- ZNF665 | c.733A>G p.R245G (on ENST00000600412; = p.R310G on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV101128784; called by muse, mutect2
- DNAH17 | c.7756del p.H2586Ifs*7 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- HAVCR2 | c.401_402insGACGT p.P136Sfs*38 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- RSPO1 | c.23T>G p.V8G | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2
- SYCP1 | c.657+4_657+7del p.X219_splice | Splice Site (DEL) | VAF 126/542 reads (23%) | called by mutect2, pindel, varscan2
- CEP192 | c.3771C>T p.S1257= | Silent (SNP) | VAF 59/163 reads (36%) | catalogued as rs777213904, COSV58060057; called by muse, mutect2, varscan2
- CHRNA2 | c.114A>G p.G38= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV53556840; called by muse, mutect2, varscan2
- COL5A1 | c.4818C>T p.D1606= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs190912679; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GRIA3 | c.2415C>T p.C805= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV52052447; called by muse, mutect2, varscan2
- IFI44L | c.705C>T p.I235= | Silent (SNP) | VAF 47/161 reads (29%) | catalogued as COSV60727016; called by muse, mutect2, varscan2
- SPTB | c.4746C>T p.D1582= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs760026396, COSV67630440; called by muse, mutect2, varscan2
- STAT3 | c.627G>A p.A209= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs759225787, COSV52885125, COSV52888064; called by muse, mutect2, varscan2
- TRAJ18 | c.24G>A p.G8= | Silent (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- TRHR | c.507C>T p.S169= | Silent (SNP) | VAF 109/353 reads (31%) | catalogued as rs962985921, COSV61233307; called by muse, mutect2, varscan2
- ZNF665 | c.732A>G p.R244= (on ENST00000600412; = p.R309= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/426 reads (5%) | catalogued as COSV101128787; called by muse, mutect2
